Somatic mutation profile of tumor specimen C3N-02590-01 (aliquot CPT0187590026) from CPTAC case C3N-02590, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.5 years (25,019 days).
Specimen C3N-02590-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7fddbb1-df1e-4a0d-ad90-639140c727cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02590-31 (Blood Derived Normal), aliquot CPT0187630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3313ad25-daf4-4b83-aab5-05857612baf5

The open-access MAF lists 34 somatic variants for this specimen: 28 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Nonsense Mutation 2, Intron 2, Silent 2, Splice Region 2, 3'UTR 1, 3'Flank 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 38/504 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.1058A>C p.Y353S | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs377767346, CM994757, COSV61688013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1G>A p.X224_splice | Splice Site (SNP) | VAF 74/536 reads (14%) | hotspot (GDC flag); catalogued as rs863224499, CS071266, CS123101, COSV52670407, COSV52712339, COSV52751788; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGEF7 | c.2510C>T p.A837V (on ENST00000646102 / NM_001354046.1; = p.A621V on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); catalogued as COSV54542143; called by muse, mutect2
- CAPN5 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 46/750 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.576); catalogued as rs374497977; called by muse, mutect2
- GRM6 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1195558693; called by muse, mutect2
- NEXMIF | c.3437C>A p.S1146Y | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV50067061; called by muse, mutect2
- OTUD4 | c.217C>T p.R73* (on ENST00000447906 / NM_001366057.1; = p.R8* on NM_017493.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/212 reads (7%) | catalogued as COSV56849995; called by muse, mutect2
- PRKAB1 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 28/445 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319163692; called by muse, mutect2
- SARDH | c.1823C>T p.T608M | Missense Mutation (SNP) | VAF 69/690 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1471841676, COSV64100100; called by muse, mutect2
- ZNF41 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 39/397 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57442573; called by muse, mutect2
- CACNA1S | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 22/640 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- CELSR3 | c.3385G>A p.D1129N | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CTAG2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 46/641 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2
- ESCO1 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 77/332 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBN1 | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 56/614 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- HDAC8 | c.1005G>A p.E335= | Splice Region (SNP) | VAF 22/206 reads (11%) | called by muse, mutect2, varscan2
- HKDC1 | c.1030A>T p.K344* | Nonsense Mutation (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- HUWE1 | c.646-7A>G | Splice Region (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- IL1RAPL1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- LLGL2 | c.479C>A p.A160D | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- MOK | c.372_374del p.F125del | In Frame Del (DEL) | VAF 18/208 reads (9%) | called by mutect2, pindel
- NT5C | c.466_467dup p.S157Qfs*36 | Frame Shift Ins (INS) | VAF 42/290 reads (14%) | called by mutect2, varscan2
- P2RX2 | c.1115T>C p.L372S | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPEF2 | c.473T>C p.V158A | Missense Mutation (SNP) | VAF 28/422 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- RANBP2 | c.3965T>C p.I1322T | Missense Mutation (SNP) | VAF 53/546 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- SERINC4 | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 76/1021 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- TAMALIN | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.867); called by muse, mutect2
- PALB2 | c.828C>T p.H276= | Silent (SNP) | VAF 50/788 reads (6%) | catalogued as rs911713488, COSV55166306; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- RFX1 | c.2478C>T p.D826= | Silent (SNP) | VAF 53/548 reads (10%) | catalogued as rs1200947508; called by muse, mutect2
- DOT1L | c.4606+672G>A | Intron (SNP) | VAF 78/950 reads (8%) | called by muse, mutect2
- IMPDH1 | c.*7C>T | 3'UTR (SNP) | VAF 37/414 reads (9%) | catalogued as rs375608202; called by muse, mutect2
- N4BP2L2 | chr13:32442398 G>A | 3'Flank (SNP) | VAF 14/156 reads (9%) | catalogued as rs762382967; called by muse, mutect2
- RGS3 | c.2038-18099G>A | Intron (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
